Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3V7, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3V7-01A (Primary Tumor).

[page 1 of 2]
Head & Neck
Head And Neck

Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

year old with multinodular goiter FNA revealed papillary thyroid cancer.

Specimens Submitted:

1: Total thyroid

DIAGNOSIS:

1. Total thyroid, thyroidectomy:

1. Total thyroid:

Part # 1

Tumor Type:

Papillary carcinoma, tall cell variant

≥ 50% tall cell features per TSS per

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Psammoma bodies

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 2.2 cm.

Tumor Encapsulation:

None identified

Blood Vessel Invasion:

Focal invasion

Extrathyroid Extension:

Invades perithyroidal fibroadipose tissue

Surgical Margins:

Microcarcinoma (0.8 cm) is less than 0.5 mm from cauterized surgical margin (left lobe)

Tumor Multicentricity:

Papillary microcarcinoma; left lobe: three foci, 0.2 cm to 0.8 cm; right lobe: one focus, 0.2 cm

Adenoma(s) (away from the carcinoma):

Not identified

Non-Neoplastic Thyroid:

Exhibits nodular hyperplasia

ICD-O-3

carcinoma, papillary, tall cell

8344/3

Site: thyroid, NOS

C73.9

5-2-12
(2)

[page 2 of 2]
Parathyroid Glands:

Identified

One normocellular parathyroid gland adjacent to the right lobe

Lymph Nodes:

Two benign perithyroidal lymph nodes (0/2)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result

Special Stain
RECUT
RECUT

Comment

Gross Description:

1. The specimen is received fresh, labeled "total thyroid, short stitch right superior pole, long stitch left lower pole", and consists of a thyroid weighing 32.5 g. The right lobe measures 4.5 x 3.5 x 2 cm, the left lobe measures 3.5 x 2.5 x 2 cm, and the isthmus measures 1.5 x 1 x 0.4 cm. The external surface is covered by a thin fibrous capsule. The anterior aspect of the thyroid, both right and left lobe are covered with small piece of skeletal muscle. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals 0.6 cm in diameter well defined nodule in the lower pole of left lobe and an ill defined nodular lesion in the right lobe, it measures 2.2 x 1.8 x 1.5 cm. It is firm and abuts the thyroid capsule. elsewhere the thyroid parenchyma is beefy red. The entire lesions of the left lobe and right lobe are submitted for permanent section. submitted. Photo is taken.

Summary of sections

RLT—right lobe nodule

LLT—left lobe nodule

RLP—right lobe gross normal thyroid tissue

LLP—left lobe gross normal thyroid tissue

IS—isthmus

Summary of Sections:

Part 1: Total thyroid

Block	Sect. Site	PCs
2	IS	3
3	LLP	4
5	LLT	6
7	RLP	8
8	RLT	9

Source: NCI Genomic Data Commons file 6ce7b6ad-78bb-4ca0-84e4-f98cfa1b6d58 (TCGA-DJ-A3V7.326E3287-2AA6-402A-B23D-9E2F020B6986.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).